Surgical pathology report (de-identified scan), TCGA case TCGA-CN-5370, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-5370-01A (Primary Tumor).

[page 1 of 7]
Pathology Report

Report Type rt
Date of Event
Sex
Authored by
Hosp/Group

PATIENT HISTORY:

No clinical history given.

PRE-OP DIAGNOSIS: Squamous cell carcinoma of tongue.

POST-OP DIAGNOSIS: Same.

URE: Partial glossectomy.

FINAL DIAGNOSIS:

PART 1: TONGUE, RIGHT, PARTIAL GLOSSECTOMY

A. INVASIVE MODERATE TO POORLY DIFFERENTIATED SQUAMOUS CELL
CARCINOMA

WITH FOCAL SPINDLE CELL AREAS (~10%) (7.0 CM) WITH EXTENSIVE INVOLVEMENT OF
TONGUE MUSCULATURE.

B. PERINEURAL INVASION PRESENT.

C. TUMOR IS PRESENT AT THE MID MEDIAL SOFT TISSUE SPECIMEN MARGIN (SEE
PART 6 FOR FINAL MARGIN).

D. PATHOLOGICAL STAGE: pT3 N1 MX.

PART 2: SOFT TISSUE, POSTERIOR MARGIN, DEEP MEDIAL, EXCISION

A. SKELETAL MUSCLE AND SALIVARY GLAND TISSUE WITH NO SIGNIFICANT
PATHOLOGIC CHANGE.

B. NO TUMOR PRESENT.

PART 3: SOFT TISSUE, POSTERIOR MEDIAL, DEEP LATERAL, EXCISION

A. SKELETAL MUSCLE AND SALIVARY GLAND TISSUE.

B. NO TUMOR PRESENT.

PART 4: MUCOSA AND SOFT TISSUE, RIGHT FLOOR OF MOUTH MARGIN, EXCISION

A. SQUAMOUS MUCOSA, FIBROADIPOSE TISSUE AND SALIVARY GLAND TISSUE
WITH NO SIGNIFICANT PATHOLOGIC CHANGE.

B. NO TUMOR PRESENT.

PART 5: LYMPH NODES, LEVEL 1 THROUGH 4, RIGHT NECK DISSECTION

A. ONE OF FORTY LYMPH NODES (1/40) WITH METASTATIC SQUAMOUS CELL
CARCINOMA (1.0 cm).

B. POSITIVE LYMPH NODE IN LEVEL III WITH EXTRACAPSULAR SPREAD.

C. SUBMANDIBULAR GLAND WITH MILD CHRONIC SIALADENITIS.

D. PORTION OF BENIGN ECTOPIC PAROTID TISSUE LEVEL II.

PART 6: SOFT TISSUE, FURTHER SOFT TISSUE MARGIN, EXCISION

A. SKELETAL MUSCLE AND FIBROADIPOSE TISSUE WITH ACUTE INFLAMMATION
AND FOCAL GRANULOMAS.

B. NO TUMOR PRESENT.

CR/cef

PART 7: DENTAL HARDWARE, EXCISION -

DENTAL HARDWARE (gross only, see comment and gross description).

The specimen (part number 7) labeled as "dental implant" has been subjected
to
a gross examination only. If it is desired that this specimen be processed

[page 2 of 7]
for additional studies, particularly microscopic examination, it is suggested that the case pathologist be notified within two weeks of the signout date of this report. This is particularly important as specimens are routinely discarded after a p me.

Pathologist: [REDACTED]

Fellow/Chi [REDACTED]

Resident: [REDACTED]

** Report [REDACTED]

My si [REDACTED] station that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

Part 1 is received unfixed for intraoperative consultation labeled with the patient' s name, initials xxx and "right hemiglossectomy." The specimen consists of an unoriented right hemiglossectomy with an attached black suture that indicates the anterior medial aspect of the specimen. The specimen is composed of a portion of tongue with a roughened mucosal surface and areas of focal hemorrhage. The specimen is 9.2 x 5.5 x 5.5 cm. Underlying the mucosa is a large, firm, white mass that infiltrates the surrounding muscle and is contiguous with an non-ulcerated surface. This lesion is large and is 7.0 x 4.5 x 4.5 cm and composes approximately 90% of the entire specimen. This lesion is 1.5 cm from the anterior margin, 2.0 cm from the dorsomedial margin,

and is present at the midmedial soft tissue margin. Approximately half of the

tumor is recovered for tumor banking. Representative sections are submitted as follows:

1AFS anterior shave margin

1BFS dorsal medial mucosa shave margin

1CFS midmedial soft tissue margin

1D thru 1E surface with adjacent normal muscle

1F thru 1G tumor with muscle

1H thru 1I tumor with mucosal surface

1J tumor with muscle.

Part 2 is received unfixed for intraoperative consultation and is labeled with

the patient' s name, initials xxx and "posterior margin, deep medial." The specimen consists of a solitary, focally hemorrhagic, firm white soft tissue fragment that is 2.1 x 1.2 x 0.3 cm. The specimen is submitted in its entirety in cassette 2AFS.

Part 3 is received unfixed for intraoperative consultation and is labeled with

the patient' s name, initials xxx and "posterior margin, deep lateral." The specimen consists of a solitary, irregular, focally hemorrhagic, firm tissue fragment that is 1.5 x 1.3 x 0.4 cm. The specimen is submitted in its entirety in cassette 3AFS.

Part 4 is received unfixed for intraoperative consultation and is labeled with

the patient' s name, initials xxx and "further right floor of mouth (stitch anterior end). " The specimen consists of a solitary, unoriented, irregular, firm tissue fragment that is 3.0 x 0.8 x 0.2 cm. The anterior portion of the specimen is inked blue and the specimen is submitted in its entirety in 4AFS.

Part 5 is received in formalin labeled with the patient' s name, initials xxx and "right neck dissection, Zones 1 through 4." The specimen consists of a focally hemorrhagic, irregular, fibrofatty tissue fragment with an attached

[page 3 of 7]
submandibular gland. The specimen is 14.5 x 8.5 x 1.5 cm. The attached gland is 3.8 x 2.7 x 1.3 cm. Sections through the submandibular gland show no evidence of a mass lesion. The remainder of the specimen is dissected for lymph nodes. Accompanying the specimen is a small, loose fragment of fibrofatty tissue that is 3.0 x 1.5 x 0.5 cm. Seven lymph nodes at multiple levels are bisected and a portion is recovered for research. Representative sections are submitted as follows:

5A level 3 node A
5B level 3 node B
5C level 4 node A
5D level 4 node B
5E level 4 node C
5F level 4 node D
5G level 4 node E
5H level 1, one lymph node bisected
5I level 1, three nodes
5J level 1, four nodes
5K level 1, four nodes
5L level 1, one node, bisected
5M thru 5O representative sections of submandibular gland
5P level 2, three nodes
5Q level 2, two nodes
5R level 3, three nodes
5S level 3, three nodes
5T level 3, four nodes
5U level 3, two nodes
5V level 4, four nodes
5W - level 4, three nodes
5X level 4, two nodes
5Y level 4, four nodes.

Part 6 is received unfixed for intraoperative consultation labeled with the patient's name, initials xxx and "further soft tissue margin (stitch)." The specimen consists of an irregular, focally hemorrhagic, firm soft tissue fragment that is 2.4 x 1.2 x 0.5 cm. The mucosal surface is identified. The specimen is bisected and submitted entirely as follows:

6AFS mucosal surface
6BFS remaining tissue.

Part 7 is received unfixed labeled with the patient's name, initials xxx and "dental implant." The specimen consists of three metal fragments. There is one fragment with a dental implant and attached threaded screw that is 1.5 x 0.8 x 0.8 cm. There is one irregular fragment of silver metal that is 0.6 x 0.5 x 0.4 cm and a third piece, which consists of a threaded screw that is 1.6 cm in length and 0.1 cm in diameter. No tissue is identified. No tissue is identified.

1. [REDACTED] VE CONSULTATION:

1A,
1B,
1C: RIGHT HEMIGLOSSECTOMY (frozen section) -
A. MALIGNANT.
B. SQUAMOUS CELL CARCINOMA WITH PERINEURAL INVASION.
C. M [REDACTED] 0 CM FROM FLOOR OF MOUTH / VENTRAL SIDES) ([REDACTED])
2A: POS [REDACTED] n section)

[page 4 of 7]
A. BENIGN.
B. NO TUMOR PRESENT ([REDACTED])
3A: POSTERIOR MARGIN DE [REDACTED]
A. BENIGN.
B. NO TUMOR PRESENT ([REDACTED])
4A: SOFT TISSUE, FURTHER [REDACTED] ERIOR) (frozen section)
A. BENIGN.
B. NO TUMOR PRESENT ([REDACTED])
6A AND
6B: SOFT TISSUE, SUPERIOR MARGIN (frozen section) -
A. BENIGN.
NO TUMOR PRESENT [REDACTED]
[REDACTED]

COPIC:

SYNOPTIC TONGUE

A.Specimen: 2

- 1.Partial glossectomy (less than half of tongue)
- 2.Hemiglossectomy
3. Total glossectomy

B.Attached Structures: 1

- 1.None
- 4.Larynx
- 2.Floor of mouth
- 5.Neck dissection
- 3.Mandible

C.Predominant side of tumor: 1

- 1.Right
- 2.Left
- 3.Midline

4.

Bilateral

D.Location of tumor: 2

- 1.Anterior two-thirds
- 5.Posterior one-third (base)
- 2.Lateral border
- 6.Anterior and posterior
- 3.Dorsal (top)
- 7.Ventral (bottom)
- 4.Tip

E.Greatest dimension of tumor: # cm

F.Histologic Type of Tumor: 1,4

- 1.Conventional squamous cell carcinoma
6. Mucoepidermoid or adenosquamous carcinoma
- 2.Papillary (exophytic) squamous cell carcinoma
7. Sarcoma
- 3.Verrucous carcinoma
8. Salivary gland type carcinoma
- 4.Spindle cell carcinoma
9. Other
- 5.Basaloid squamous carcinoma

G.Tumor differentiation: 2-3

- 1.Welldifferentiated
- 2.Moderately differentiated
3. Poorly or undifferentiated

H.Structures involved: 1

- 1.Limited to tongue
- 4.Bone (mandible)
- 2.Floor of mouth
- 5.Vallecular or larynx

[page 5 of 7]
3. Gingiva
6. Other

I. Does tumor grossly or microscopically cross the midline? 2
1. Yes 2. No

J. Depth of invasion of tongue: 4
1. In-situ 3. Superficial muscle
2. Lamina propria 4. Deep muscle

K. Intra-perineural invasion: 1
1. Yes 2. No

L. Angiolymphatic Invasion: 2
1. Yes 2. No

M. Surgical margins: 2
1. Free (5 mm or more)

4. Positive for high grade dysplasia
2. Close (within 5 mm)

5. Positive for in-situ carcinoma
3. Positive for low or moderate grade dysplasia 6.
Positive for invasive carcinoma

N. Number of positive lymph nodes: 1

O. Total number of lymph nodes examined: 40

P. Extracapsular spread of lymph node metastasis: 1
1. Yes 2. No

Q. TNM Stage: T 3N 1M X

Parts 1-6: Microscopic examination substantiates the above diagnosis.

Part 7: No sections submitted

Procedural Notes

Lymph node	FS	Perm
-Level III node A	neg	neg
-Level III node B	pos	pos
-Level IV node A	neg	neg
-Level IV node B	neg	neg
-Level IV node C	neg	neg
-Level IV node D	neg	neg
-Level IV node E	neg	neg

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The [redacted] and its performance characteristics determined by the [redacted], Department of Pathology, as required by the C.A.

[redacted] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: [redacted] ctomy (hemi) ri

Taken [redacted] Received: [redacted]

Stain [redacted]

H&E x	D
H&E x 1	E
H&E x 1	F
H&E x 1	G
H&E x 1	H
H&E x 1	I

[page 6 of 7]
H&E x 1 J
FRZ Single x 1 AFS
H&E x 1 AFS
FRZ Addit x 1 BFS
H&E x 1 BFS
FRZ Addit x 1 CFS
H&E x 1 CFS

Part 2: in deep medial

Taken: Received:

Stain/c

FRZ Single x 1 AFS
H&E x 1 AFS

Part 3: in deep lateral

Taken: Received:

Stain/c

FRZ Single x 1 AFS
H&E x 1 AFS

Part 4: floor of mouth

Taken: Received:

Stain/c

FRZ Single x 1 AFS
H&E x 1 AFS

Part 5: section zones I

Taken: Received:

Stain/c

H&E x 1 A
H&E x 1 B
H&E x 1 C
H&E x 1 D
H&E x 1 E
H&E x 1 F
H&E x 1 G
H&E x 1 H
H&E x 1 I
H&E x 1 J
H&E x 1 K
H&E x 1 L
H&E x 1 M
H&E x 1 N
H&E x 1 O
H&E x 1 P
H&E x 1 Q
H&E x 1 R
H&E x 1 S
H&E x 1 T
H&E x 1 U
H&E x 1 V
H&E x 1 W
H&E x 1 X
H&E x 1 Y

Part 6: issue margin

Taken: Received:

Stain/c

FRZ Single x 1 AFS
H&E x 1 AFS
FRZ Addit x 1 BFS
H&E x 1 BFS

[page 7 of 7]
Part 7:

Taken:

TC1

Received:

Source: NCI Genomic Data Commons file 5cf5d7b7-e449-4cf5-9028-9100bcc1beac (TCGA-CN-5370.95836162-4125-44B7-83C3-9919D2AE068C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).